Gene-level copy-number profile of tumor specimen TCGA-DX-A1L3-01A from TCGA case TCGA-DX-A1L3, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.9 years (22,240 days).
Specimen TCGA-DX-A1L3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4c87e44d-f539-4efc-b6fb-bdd0561b7219.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1L3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e8bf11b-77c7-4641-8a72-a5fb2f20fec6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 941; copy number 4: 57,338; copy number 5: 17; copy number 6: 734; copy number 9: 55; copy number 10: 94; copy number 11: 59; copy number 12: 69; copy number 13: 1; copy number 14: 9; copy number 15: 4; copy number 16: 12; copy number 17: 53; copy number 18: 3; copy number 19: 6; copy number 21: 20; copy number 26: 34; copy number 27: 19; copy number 28: 50; copy number 29: 51; copy number 33: 16; copy number 37: 37; copy number 42: 15; copy number 45: 5; copy number 46: 6; copy number 47: 1; copy number 53: 2; copy number 54: 10; copy number 55: 8; copy number 59: 36; copy number 64: 39; copy number 71: 1; copy number 72: 1; copy number 74: 2; copy number 80: 10; copy number 81: 18; copy number 82: 40; copy number 85: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1L3-01A-11D-A24M-01): tumor purity 0.61, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 785 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,769,339–164,980,137, 14 genes, copy number 27–42: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:167,220,876–173,064,015, 132 genes, copy number 19–64 (within-gene range 4–64) (broad region; genes not listed).
- chr5:58,198–1,295,068, 47 genes, copy number 17: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:10,195,121–14,532,128, 49 genes, copy number 9–17 (within-gene range 2–17): AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:15,110,786–15,496,353, 5 genes, copy number 12: U8, LINC02149, MARK2P5, AC114964.2, AC114964.1.
- chr5:15,602,189–15,619,109, 1 gene, copy number 12: CTD-2350J17.1.
- chr5:20,158,662–20,158,956, 1 gene, copy number 13: AC093303.1.
- chr5:22,580,225–23,689,386, 10 genes, copy number 11–16: GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:29,239,922–29,983,114, 9 genes, copy number 16: AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr5:31,908,361–31,936,159, 3 genes, copy number 14: TPT1P5, AC025458.1, MIR4279.
- chr5:36,861,736–37,377,971, 14 genes, copy number 10: AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1.
- chr5:38,345,347–38,671,216, 8 genes, copy number 11 (within-gene range 6–11): EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650.
- chr5:40,415,137–40,860,175, 11 genes, copy number 11: AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6.
- chr5:43,444,252–45,895,970, 29 genes, copy number 11: TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:958,323–1,324,022, 6 genes, copy number 14: LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394.
- chr6:4,702,463–4,955,551, 4 genes, copy number 15: PSMC1P11, CDYL, AL356747.1, CDYL-AS1.
- chr6:13,924,446–15,522,042, 22 genes, copy number 9 (within-gene range 4–9): RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P.
- chr12:18,242,961–19,376,400, 14 genes, copy number 46–80 (within-gene range 4–80): PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:19,413,153–19,419,161, 2 genes, copy number 80: PDCD5P1, AC091805.2.
- chr12:57,693,955–59,064,238, 36 genes, copy number 59 (within-gene range 4–59): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2.
- chr12:68,248,242–68,332,381, 2 genes, copy number 18: IL22, MDM1.
- chr12:68,344,664–68,349,959, 1 gene, copy number 18: AC022511.1.
- chr12:68,674,371–70,243,379, 40 genes, copy number 82: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.
- chr12:73,159,190–73,208,317, 2 genes, copy number 26 (within-gene range 4–26): LINC02444, AC090503.1.
- chr12:73,820,315–74,545,430, 9 genes, copy number 33–74 (within-gene range 5–74): LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1.
- chr12:75,020,969–75,298,508, 4 genes, copy number 33–85 (within-gene range 23–93): AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1.
- chr12:75,305,452–75,306,357, 1 gene, copy number 33: AC092552.1.
- chr12:75,649,195–75,698,816, 4 genes, copy number 54: AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:77,775,783–77,783,576, 1 gene, copy number 71: AC138331.1.
- chr12:78,863,993–79,452,008, 2 genes, copy number 53 (within-gene range 4–77): SYT1, AC090709.1.
- chr12:84,448,625–85,036,277, 5 genes, copy number 11–72: AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19.
- chr12:88,430,442–88,602,195, 5 genes, copy number 54: Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr12:89,027,757–89,028,522, 1 gene, copy number 54: AC006199.1.
- chr12:93,677,375–93,943,603, 5 genes, copy number 33 (within-gene range 4–33): CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1.
- chr12:95,791,733–96,269,824, 17 genes, copy number 81: AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2.
- chr12:96,303,375–96,303,513, 1 gene, copy number 81: RNU4-24P.
- chr15:33,858,782–34,108,686, 8 genes, copy number 55 (within-gene range 4–55): AVEN, CHRM5, AC009268.2, AC009268.3, AC009268.1, EMC7, AC079203.1, PGBD4.
- chr15:65,611,366–67,542,604, 50 genes, copy number 28: SLC24A1, AC011939.3, DENND4A, SNORD13E, MIR4511, RAB11A, AC011939.2, AC011939.1, HNRNPA1P44, U6, MEGF11, MIR4311, AC055855.2, DIS3L, AC055855.1, TIPIN, SCARNA14, Y_RNA, RPL9P25, MAP2K1, ATP5MFP6, RPL35AP32, AC116913.1, SNAPC5, MIR4512, RPL4, SNORD18C, AC116913.2, SNORD18B, SNORD16, SNORD18A, ZWILCH, LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1.
- chr18:20,946,906–32,779,286, 203 genes, copy number 10–29 (broad region; genes not listed).
- chr19:7,069,703–7,472,484, 6 genes, copy number 45–47 (within-gene range 45–80): ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
